Somatic mutation profile of tumor specimen 0DOV95 from CCDI case PBCBKR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.6 years (576 days).
Specimen 0DOV95: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6903d599-34db-4cc4-b2e0-a05456c20047.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOV8F (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5be99490-ed6e-4f6a-9310-072841d99b07

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL19A1 | c.1156C>A p.P386T | Missense Mutation (SNP) | VAF 44/449 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ADAMTS20 | c.1770C>T p.N590= | Silent (SNP) | VAF 47/326 reads (14%) | catalogued as rs763702051, COSV67127794; called by muse, mutect2, varscan2
